Somatic mutation profile of tumor specimen MP2PRT-PASMKY-TMP1-A (aliquot MP2PRT-PASMKY-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASMKY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,273 days).
Specimen MP2PRT-PASMKY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef0da9e1-99ce-40aa-a470-f72090974d91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMKY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMKY-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c27962a7-08a2-40e1-a92b-83a6fa5e2cd3

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Frame Shift Ins 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 141/347 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ACTR2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV53200653; called by muse, mutect2, varscan2
- ADORA2A | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 330/745 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748680136; called by muse, mutect2, varscan2
- CER1 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 459/546 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs778239978; called by muse, mutect2, varscan2
- LAMA2 | c.6883C>T p.R2295C | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773802779, COSV101370304; called by muse, mutect2, varscan2
- SPRR2A | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 225/645 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.04); catalogued as rs902317665; called by muse, mutect2, varscan2
- CKAP2 | c.1827_1828insTCCT p.D610Sfs*2 (on ENST00000378037 / NM_001098525.2; = p.D609Sfs*2 on NM_018204.5) | Frame Shift Ins (INS) | VAF 54/179 reads (30%) | called by mutect2, pindel, varscan2
- DHX29 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 141/280 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- E2F8 | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 169/490 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAG1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 176/434 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCZ1 | c.1762T>C p.F588L | Missense Mutation (SNP) | VAF 137/319 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRSF10 | c.365_366insGT p.S123* | Frame Shift Ins (INS) | VAF 106/374 reads (28%) | called by pindel, varscan2
- USP36 | c.2497A>G p.I833V | Missense Mutation (SNP) | VAF 270/666 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.01); called by muse, mutect2
- VPS13C | c.10810G>T p.G3604C (on ENST00000644861 / NM_020821.3; = p.G3561C on NM_017684.5) | Missense Mutation (SNP) | VAF 148/399 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRI3BP | c.384G>A p.L128= | Silent (SNP) | VAF 296/687 reads (43%) | catalogued as COSV58297645; called by muse, mutect2, varscan2
- NEFL | c.24G>T p.P8= | Silent (SNP) | VAF 256/530 reads (48%) | catalogued as COSV99647810; called by muse, mutect2, varscan2
